CPTAC case C3N-07000 — Skin — Nevi and Melanomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Nevi and Melanomas; Primary site: Skin. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ac22e80f-b824-4e37-8515-f67c9e0dbf69

Demographics
Sex at birth: male; Race: white; Year of birth: 1969; Vital status: Alive; Country of birth: Poland.

Diagnoses (1)
1. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Skin of scalp and neck; Age at diagnosis: 52.2 years (19,084 days); Year of diagnosis: 2021; AJCC staging edition: 8th; AJCC clinical M: M0; AJCC pathologic T: T4b; AJCC pathologic N: N2c; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIC; Residual disease: RX; Last known disease status: With tumor; Days to last known disease status: 813 days (2.2 years); Progression or recurrence: yes; Days to last follow up: 813 days (2.2 years); Clark level: III; Tumor focality: Unifocal; Ulceration indicator: Yes.
   Pathology details: Breslow thickness category: >4.0 mm; Greatest tumor dimension: 3 cm; Lymph node involvement: Positive; Lymph nodes positive: 1; Lymph nodes tested: 24; Lymphatic invasion present: Yes; Margin status: Uninvolved; Perineural invasion present: No; Vascular invasion present: Yes.

Follow-up (2 entries)
- Days to follow up: 383 days (1.0 years); Disease response: Tumor Free; Karnofsky performance status: 100; ECOG performance status: 0.
- Days to follow up: 813 days (2.2 years); Disease response: With Tumor; Karnofsky performance status: 80; ECOG performance status: 2.

Exposures
- Tobacco smoking status: Current Smoker; Cigarettes per day: 20; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-07000-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Head & Neck; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 1 day; Initial weight: 92 mg; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-07000-21: Section location: Head & neck; Percent tumor nuclei: 75; Percent necrosis: 2.
- Sample C3N-07000-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 1 day; Method of sample procurement: Blood Draw.
